Somatic mutation profile of tumor specimen ALCH-B3AT-TTP1-A (aliquot ALCH-B3AT-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.6 years (18,495 days).
Specimen ALCH-B3AT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31b5df9c-578c-4c50-a3b9-b5224e6d7257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AT-NB1-A (Blood Derived Normal), aliquot ALCH-B3AT-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96ca7fd7-bfd5-4dbe-a896-716254e2dbc5

The open-access MAF lists 1,636 somatic variants for this specimen: 949 protein-altering or splice-affecting, 476 silent, 211 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 849, Silent 476, Intron 99, Nonsense Mutation 58, 3'UTR 36, RNA 30, 5'Flank 23, Splice Region 17, 5'UTR 17, Splice Site 17, 3'Flank 6, Frame Shift Del 4.

Variants (750 of 1,636; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 126/641 reads (20%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 122/758 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 56/557 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1474762209; called by muse, mutect2, varscan2
- AASS | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 66/1281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148068419; called by muse, mutect2
- ABCA6 | c.4081C>T p.Q1361* | Nonsense Mutation (SNP) | VAF 50/723 reads (7%) | catalogued as rs1405130980; called by muse, mutect2
- AC011479.1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100007805; called by muse, mutect2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 41/547 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2
- ACD | c.805G>A p.G269R (on ENST00000620338; = p.G180R on NM_022914.3) | Missense Mutation (SNP) | VAF 32/531 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV99537899; called by muse, mutect2
- ACP6 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207464798; called by muse, mutect2, varscan2
- ACSM2A | c.967C>T p.L323F (on ENST00000219054; = p.L244F on NM_001308169.2) | Missense Mutation (SNP) | VAF 48/636 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV54591095; called by muse, mutect2
- ACTC1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.997); catalogued as rs1368192263, COSV51759788; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAMTS17 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 76/596 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs141306868; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV57860851; called by muse, mutect2
- ADGRL2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 60/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54679818; called by muse, mutect2, varscan2
- AKR1C3 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 26/461 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV65910393, COSV65910823; called by muse, mutect2
- ALAS2 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as rs372076630; called by muse, mutect2, varscan2
- ALX3 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 62/547 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767866679; called by muse, mutect2, varscan2
- AMBRA1 | c.2581C>T p.R861W (on ENST00000458649 / NM_001367468.1; = p.R771W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/689 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs774567886, COSV100094498; called by muse, mutect2, varscan2
- ANKIB1 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 36/403 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV56059500; called by muse, mutect2, varscan2
- ANKIB1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV56059509; called by muse, mutect2
- ANKRD34C | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1290343084, COSV69854980; called by muse, mutect2
- ANPEP | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 29/542 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1417320487; called by muse, mutect2
- AOC1 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs758936955; called by mutect2, varscan2
- APOB | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 48/687 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs772171897; ClinVar: uncertain significance; called by muse, mutect2
- APOL1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as rs1309772809; called by muse, mutect2, varscan2
- APP | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 94/1046 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as rs1386984902; called by muse, mutect2
- AQP2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs779279677, COSV52229857; called by muse, mutect2, varscan2
- AQP8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 47/752 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845861; called by muse, mutect2
- ARHGAP11A | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs766956038, COSV55708206; called by muse, mutect2, varscan2
- ARHGAP31 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 70/912 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs781008921; called by muse, mutect2
- ARMC5 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs755194677; called by muse, varscan2
- ARSG | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244718647; called by muse, mutect2
- ASIC1 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs867130198, COSV57318881, COSV99948305; called by muse, mutect2
- ASTN2 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99046504; called by muse, mutect2, varscan2
- ATP10A | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1445184868; called by muse, mutect2
- ATP10B | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1253567786; called by muse, mutect2, varscan2
- ATP10B | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100469189; called by muse, mutect2
- ATP11A | c.1026C>T p.F342= | Splice Region (SNP) | VAF 36/241 reads (15%) | catalogued as rs1387394606, COSV52124509; called by muse, mutect2, varscan2
- ATXN7L1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1393788601, COSV66301237; called by muse, mutect2
- B3GNT2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs370583197; called by muse, mutect2, varscan2
- BAZ1B | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV59989470, COSV59994618; called by muse, mutect2, varscan2
- BBS9 | c.1922C>T p.P641L (on ENST00000242067 / NM_001348036.1; = p.P601L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775954730; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 83/872 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs778390668, COSV100863734; called by muse, mutect2
- BLVRA | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 295/1499 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.901); catalogued as COSV55512948; called by muse, mutect2, varscan2
- BNIP2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99985760; called by muse, mutect2, varscan2
- BOLL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377264153; called by muse, mutect2, varscan2
- BPIFB4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 71/679 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs140887073; called by muse, mutect2, varscan2
- BPTF | c.6716C>T p.S2239F | Missense Mutation (SNP) | VAF 42/1016 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs868961300; called by muse, mutect2
- BRINP1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.879); catalogued as rs1247843831, COSV56296057; called by muse, mutect2, varscan2
- BTBD8 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 43/463 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.148); catalogued as rs369486791; called by muse, mutect2
- CA4 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 46/954 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283856720; called by muse, mutect2
- CAD | c.6317C>T p.P2106L | Missense Mutation (SNP) | VAF 62/505 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV53023310; called by muse, mutect2, varscan2
- CALCRL | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as rs1274060288, COSV66474682; called by muse, mutect2
- CAPN3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 102/1109 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as CD951643, COSV55521974; called by muse, mutect2
- CARF | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 62/609 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.117); catalogued as COSV57549125; called by muse, mutect2, varscan2
- CCDC112 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1011646731; called by muse, mutect2
- CCDC134 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs1326490150, COSV55388573, COSV55388864; called by muse, mutect2, varscan2
- CCDC184 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs759097956; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 51/577 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2
- CD6 | c.1200G>T p.M400I | Missense Mutation (SNP) | VAF 94/544 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs751038603; called by muse, mutect2, varscan2
- CDC42BPA | c.3412G>A p.D1138N (on ENST00000334218 / NM_001366019.2; = p.D1125N on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62008901; called by muse, mutect2, varscan2
- CDC45 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 64/679 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs772885663; called by muse, mutect2
- CDH2 | c.2671G>A p.G891R | Missense Mutation (SNP) | VAF 60/872 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764584049; called by muse, mutect2
- CDH2 | c.2670G>A p.W890* | Nonsense Mutation (SNP) | VAF 60/880 reads (7%) | catalogued as COSV52292080; called by muse, mutect2
- CDH20 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1194504167; called by muse, mutect2
- CECR2 | c.584G>A p.G195E (on ENST00000342247 / NM_001290047.2; = p.G32E on NM_001290046.1) | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as COSV52844775; called by muse, mutect2
- CECR2 | c.872G>A p.G291E (on ENST00000342247 / NM_001290047.2; = p.G128E on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52847521; called by muse, mutect2
- CEMIP2 | c.2267+1G>A p.X756_splice | Splice Site (SNP) | VAF 32/262 reads (12%) | catalogued as rs967250751; called by muse, mutect2, varscan2
- CERCAM | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770566413, COSV65710889; called by muse, mutect2, varscan2
- CFAP44 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 80/440 reads (18%) | catalogued as rs1464188431; called by muse, mutect2, varscan2
- CFHR5 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56820021; called by muse, mutect2, varscan2
- CHD6 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV100498694, COSV58556043; called by muse, mutect2
- CHL1 | c.1841C>T p.P614L (on ENST00000397491 / NM_001253387.1; = p.P630L on NM_006614.4) | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772990615, COSV56594382; called by muse, mutect2, varscan2
- CLASP1 | c.3241C>T p.L1081F | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1265917588; called by muse, mutect2
- CLCN1 | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.149); catalogued as rs1317251527, COSV58370410; called by muse, mutect2, varscan2
- CLSTN3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 73/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1262922234; called by muse, mutect2, varscan2
- CNGB1 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 84/955 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1314615095; called by muse, mutect2
- COG8 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV54743349; called by muse, mutect2
- COL19A1 | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 51/367 reads (14%) | catalogued as CS135979; called by muse, mutect2, varscan2
- COL1A1 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56805372; called by muse, mutect2
- COL6A3 | c.5621G>A p.R1874K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55113691, COSV99797060; called by muse, mutect2, varscan2
- CPAMD8 | c.3434G>A p.S1145N (on ENST00000651564; = p.S1098N on NM_015692.5) | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.997); catalogued as rs1348509554; called by muse, mutect2
- CRB1 | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV66333601; called by muse, mutect2
- CREBRF | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs935447459, COSV51632494, COSV99755602; called by muse, mutect2, varscan2
- CST8 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 54/390 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55670502, COSV55672064; called by muse, mutect2, varscan2
- CUX1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52896663; called by muse, mutect2, varscan2
- CYP46A1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 35/492 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1300487337, COSV55897198; called by muse, mutect2
- DCAF12L1 | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV64421260, COSV64421750; called by muse, mutect2, varscan2
- DDI1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV56372611; called by muse, mutect2, varscan2
- DDRGK1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 54/623 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776117912, COSV100621489; called by muse, mutect2
- DDTL | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs749759884; called by muse, mutect2, varscan2
- DISP1 | c.2710C>T p.H904Y | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1298800689; called by muse, mutect2, varscan2
- DMPK | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.737); catalogued as rs904306743; called by muse, mutect2
- DNAH3 | c.10490G>A p.G3497E | Missense Mutation (SNP) | VAF 79/567 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1271302703, COSV54545329; called by muse, mutect2, varscan2
- DNAH5 | c.3170C>T p.S1057F | Missense Mutation (SNP) | VAF 94/970 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54231470; called by muse, mutect2
- DNAJC16 | c.1778+7C>T | Splice Region (SNP) | VAF 16/267 reads (6%) | catalogued as COSV101012572; called by muse, mutect2
- DNM3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62465510; called by muse, mutect2, varscan2
- DOCK8 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV66632836; called by muse, mutect2, varscan2
- DQX1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV66352992; called by muse, mutect2, varscan2
- DSC2 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1567980622; ClinVar: uncertain significance; called by muse, mutect2
- DSEL | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100026195; called by muse, mutect2, varscan2
- DUSP21 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs767788882, COSV100173696; called by muse, mutect2, varscan2
- DYNLL1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV99655586; called by muse, mutect2
- ELK4 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 58/725 reads (8%) | catalogued as COSV56984905; called by muse, mutect2
- EML1 | c.2237G>T p.C746F | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99031448; called by muse, mutect2, varscan2
- EPB41L4A | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV99814046; called by muse, mutect2, varscan2
- ERI2 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205063160, COSV55502913; called by muse, mutect2, varscan2
- ETV6 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV67149200; called by muse, mutect2, varscan2
- FAF1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424171415; called by muse, mutect2
- FAM111A | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as CM154066; called by muse, mutect2, varscan2
- FAM166B | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 177/915 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs1335338014; called by muse, mutect2, varscan2
- FAM47C | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV63729787; called by muse, mutect2, varscan2
- FARS2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51169869; called by muse, mutect2, varscan2
- FARS2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99212901; called by muse, mutect2, varscan2
- FCGBP | c.8388+1G>A p.X2796_splice | Splice Site (SNP) | VAF 18/418 reads (4%) | catalogued as rs1452504336; called by muse, mutect2
- FCHSD1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as rs1013026558; called by muse, mutect2, varscan2
- FCRL3 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1301144757; called by muse, mutect2, varscan2
- FCRL5 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs754338427; called by muse, mutect2, varscan2
- FIGNL1 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546235904, COSV63553448; called by muse, mutect2, varscan2
- FN1 | c.4052G>A p.R1351K | Missense Mutation (SNP) | VAF 90/914 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775863568; called by muse, mutect2
- FOXK2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs780073535; called by muse, mutect2, varscan2
- FOXK2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs749538437, COSV100082517; called by muse, mutect2, varscan2
- FTMT | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV58420682; called by muse, mutect2, varscan2
- GAA | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1202479765; called by muse, mutect2, varscan2
- GARS1 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 90/732 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV66829668; called by muse, mutect2, varscan2
- GATB | c.1527G>A p.M509I | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99858937; called by muse, mutect2
- GBP6 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 56/678 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144066091; called by muse, mutect2
- GCNT1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057387; called by muse, mutect2, varscan2
- GEMIN4 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs950948866; called by muse, mutect2, varscan2
- GFRA4 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.951); catalogued as rs1271522333; called by muse, mutect2, varscan2
- GIMAP1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs372451334, COSV100212145; called by muse, mutect2, varscan2
- GJC3 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 53/709 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs149872164; called by muse, mutect2
- GK | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66734822; called by muse, mutect2, varscan2
- GLI2 | c.3308C>T p.S1103F (on ENST00000361492 / NM_001374353.1; = p.S1120F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/731 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs975278086, COSV58050946; called by muse, varscan2
- GPCPD1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs778090924, COSV66832075; called by muse, mutect2, varscan2
- GREB1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 58/495 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376668046, COSV52179909; called by muse, varscan2
- GRIN2A | c.2666G>A p.G889E | Missense Mutation (SNP) | VAF 89/650 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV58021545; called by muse, mutect2, varscan2
- GRIN2A | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 104/1006 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58050715; called by muse, mutect2, varscan2
- GRM3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 66/508 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64481038; called by muse, mutect2, varscan2
- HACE1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 211/1342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767982277, COSV53501299; called by muse, mutect2, varscan2
- HAPLN3 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1018608483; called by muse, mutect2
- HDC | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 111/949 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs1266939845; called by muse, mutect2, varscan2
- HECTD3 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99870289; called by muse, mutect2
- HERC2 | c.9650C>T p.S3217F | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55354517; called by muse, mutect2, varscan2
- HK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 121/1252 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.584); catalogued as rs1025848067; called by muse, mutect2
- HK1 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 122/1254 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs766565453; ClinVar: uncertain significance; called by muse, mutect2
- HKDC1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV63578020; called by muse, mutect2, varscan2
- HKDC1 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.61); catalogued as rs758906817, COSV63577141; called by muse, mutect2, varscan2
- HMOX1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV53340314; called by muse, mutect2
- HNRNPH1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61485846, COSV61488433; called by muse, mutect2, varscan2
- HYAL4 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56138678; called by muse, mutect2
- IDI2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs61738901, COSV52987214; called by muse, mutect2, varscan2
- IGHE | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.433); catalogued as rs371443376; called by muse, mutect2
- IKBIP | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | catalogued as rs186661099, COSV61081779; called by muse, mutect2, varscan2
- IL36B | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 14/349 reads (4%) | catalogued as rs1250230413; called by muse, mutect2
- IMPDH1 | c.169C>T p.R57W (on ENST00000470772 / NM_001142573.2; = p.R142W on NM_000883.4) | Missense Mutation (SNP) | VAF 149/904 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs376769056; called by muse, mutect2, varscan2
- INHBA | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 67/501 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as rs1397640362, COSV54219824; called by muse, mutect2, varscan2
- IRAK1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1557128410; called by muse, mutect2, varscan2
- IRF4 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 148/632 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.083); catalogued as rs774593906, COSV101110874; called by muse, varscan2
- JPH3 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1450639653; called by muse, mutect2, varscan2
- KCNJ11 | c.804C>G p.Y268* | Nonsense Mutation (SNP) | VAF 33/487 reads (7%) | catalogued as COSV60595154; called by muse, mutect2
- KCNJ12 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs111766997; called by muse, mutect2
- KCNJ6 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 41/548 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55708970; called by muse, mutect2
- KCNMB2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104420820; called by muse, mutect2
- KHK | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 35/381 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1234549588, COSV99565383; called by muse, mutect2
- KLHL1 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64767890; called by muse, mutect2
- KLHL35 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 46/572 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs944197782, COSV61128555; called by muse, mutect2
- KPTN | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.816); catalogued as COSV52639237; called by muse, mutect2, varscan2
- KXD1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs748459714; called by muse, mutect2, varscan2
- LAD1 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 46/509 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.714); catalogued as COSV66212514; called by muse, mutect2
- LAMA2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 110/747 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV70355091; called by muse, mutect2, varscan2
- LARGE1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 60/579 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1460224950, COSV61659030; called by muse, mutect2, varscan2
- LILRB4 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs752751174; called by muse, mutect2
- LIMK2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762005629; called by muse, mutect2
- LMBRD1 | c.1427A>T p.H476L (on ENST00000649011; = p.H454L on NM_018368.4) | Missense Mutation (SNP) | VAF 74/597 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs778063802; called by muse, mutect2, varscan2
- LRP1B | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV101262115, COSV67182187; called by muse, mutect2
- LRRC47 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs542812217, COSV65563737; called by muse, mutect2
- LRRC7 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 39/415 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs750067971; called by muse, mutect2
- LRRK1 | c.2005G>A p.G669R | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV52621958; called by muse, mutect2, varscan2
- LRRTM4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV69138984; called by muse, mutect2
- LRTM2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV54565479; called by muse, mutect2, varscan2
- LUC7L2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs759175269; called by muse, mutect2, varscan2
- LYZL2 | c.279G>A p.W93* (on ENST00000375318; = p.W47* on NM_183058.3) | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100940613; called by muse, mutect2
- MAGEB1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV66776322; called by muse, mutect2, varscan2
- MAGEB4 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV66775846; called by muse, mutect2, varscan2
- MAGI3 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs199499178; called by muse, mutect2, varscan2
- MAML1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 62/614 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as rs578168072, COSV99483325; called by muse, mutect2
- MAP3K15 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1230409748, COSV58829431; called by muse, mutect2, varscan2
- MAPK3 | c.907+4C>T | Splice Region (SNP) | VAF 26/214 reads (12%) | catalogued as rs767114348; called by muse, mutect2, varscan2
- MARCHF1 | c.766G>A p.V256I (on ENST00000274056; = p.V239I on NM_017923.4) | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs368441105; called by muse, mutect2
- MAST1 | c.3707C>T p.P1236L | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52248225; called by muse, mutect2, varscan2
- MAST4 | c.5921C>T p.S1974F (on ENST00000403625 / NM_001164664.2; = p.S1785F on NM_015183.3) | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1491002848; called by muse, mutect2
- MATN4 | c.1324C>T p.R442C (on ENST00000372754; = p.R401C on NM_003833.4) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | PolyPhen probably damaging (0.953); catalogued as rs750693265, COSV61350352; called by muse, mutect2, varscan2
- MBD6 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as COSV99053347; called by muse, mutect2, varscan2
- MBOAT2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs768362605; called by muse, mutect2
- MDFI | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 205/588 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs760805003; called by muse, mutect2, varscan2
- MESD | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1300723498; called by muse, varscan2
- MGAM | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV72075435; called by muse, mutect2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2
- MPLKIP | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 97/769 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1188761503; called by muse, mutect2, varscan2
- MRAP2 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 66/576 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV57633142; called by muse, mutect2, varscan2
- MRAP2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 66/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57634751; called by muse, mutect2, varscan2
- MS4A1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 65/482 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV61942241; called by muse, mutect2, varscan2
- MUC16 | c.39277G>A p.G13093R | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.012); catalogued as COSV66691145; called by muse, mutect2
- MUC16 | c.37690C>T p.P12564S | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV67467693; called by muse, mutect2
- MUC16 | c.19948G>A p.E6650K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV67468360; called by muse, mutect2, varscan2
- MUC16 | c.7551G>A p.M2517I | Missense Mutation (SNP) | VAF 55/522 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1258310982, COSV101202477; called by muse, mutect2, varscan2
- MUC16 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 53/504 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs976720011, COSV101200989; called by muse, mutect2
- MUC16 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.096); catalogued as COSV67495683; called by muse, mutect2
- MUC5B | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753423880, COSV71593917; called by muse, mutect2, varscan2
- MUL1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1329209285; called by muse, mutect2
- MYCN | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55260551; called by muse, mutect2, varscan2
- MYH11 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs761131497; called by muse, varscan2
- MYH7B | c.2641T>G p.F881V | Missense Mutation (SNP) | VAF 46/703 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99483054; called by muse, mutect2
- MYO1D | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433956761, COSV100554336; called by muse, mutect2
- NBPF12 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 86/1268 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.942); catalogued as rs1239134875; called by muse, mutect2
- NCOA2 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs935404994; called by muse, mutect2
- NEK4 | c.2086G>A p.G696R | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs769765502; called by muse, mutect2
- NEUROG1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs776636503; called by mutect2, varscan2
- NFATC4 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51607650; called by muse, mutect2
- NFKBIZ | c.869del p.S290Ffs*7 | Frame Shift Del (DEL) | VAF 78/553 reads (14%) | catalogued as COSV58201948; called by mutect2, pindel, varscan2
- NIT1 | c.480del p.K161Rfs*7 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | catalogued as COSV63501274; called by mutect2, varscan2
- NKX3-1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs192773652, COSV66512382; called by muse, mutect2, varscan2
- NLRP7 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 54/1034 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1355632267, COSV60172417; called by muse, mutect2
- NLRP8 | c.3071T>A p.I1024K | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1012248493; called by muse, mutect2
- NOS2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs199863768; called by mutect2, varscan2
- NOTCH1 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 38/760 reads (5%) | catalogued as COSV53026237, COSV99493323; called by muse, mutect2
- NOTCH1 | c.743-1G>A p.X248_splice | Splice Site (SNP) | VAF 141/874 reads (16%) | catalogued as CS149814; called by muse, mutect2, varscan2
- NOVA1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV57475079; called by muse, mutect2
- NR1H3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68008966; called by muse, mutect2
- NR1H3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 28/637 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68008969; called by muse, mutect2
- NUP155 | c.3255C>A p.Y1085* (on ENST00000231498 / NM_153485.3; = p.Y1026* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 72/645 reads (11%) | catalogued as COSV104371401; called by muse, mutect2, varscan2
- OBSCN | c.16643C>T p.S5548L | Missense Mutation (SNP) | VAF 39/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751293477, COSV52760925; called by muse, mutect2
- OR13C3 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 43/816 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66165965; called by muse, mutect2
- OR1A1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV58403219; called by muse, mutect2, varscan2
- OR1B1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs757251330, COSV59171979; called by muse, mutect2, varscan2
- OR2M7 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 52/612 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138244705, COSV100522472; called by muse, mutect2
- OR4M1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1201459761, COSV60059954; called by muse, mutect2
- OR5L1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.038); catalogued as COSV61735307; called by muse, mutect2, varscan2
- OSGEP | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 56/817 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs755761410, COSV52831249; called by muse, mutect2
- P2RY2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as rs867192171; called by muse, mutect2, varscan2
- PACS2 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV57652375; called by muse, mutect2
- PALB2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 91/1292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55169517, COSV55169959; called by muse, mutect2
- PASK | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 79/766 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52151055; called by muse, mutect2, varscan2
- PATJ | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1246765514; called by muse, mutect2, varscan2
- PCDH12 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 65/457 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs751849057; called by muse, mutect2, varscan2
- PCDH17 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs561876211; called by muse, mutect2, varscan2
- PCDHA5 | c.2088C>G p.N696K | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs139591086, COSV100972034; called by muse, mutect2
- PCDHGA6 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV53948127, COSV99546360; called by muse, mutect2, varscan2
- PCDHGA6 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as COSV99542963; called by muse, mutect2, varscan2
- PCDHGA7 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 72/575 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV99545716; called by muse, mutect2, varscan2
- PCLO | c.10684G>A p.G3562R | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61653885; called by muse, mutect2
- PCNP | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54575800; called by muse, varscan2
- PCNT | c.3131G>A p.G1044E | Missense Mutation (SNP) | VAF 16/445 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV64029258; called by muse, mutect2
- PDLIM3 | c.221G>A p.R74Q (on ENST00000284770 / NM_001257963.1; = p.R241Q on NM_014476.6) | Missense Mutation (SNP) | VAF 45/620 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775988516; called by muse, mutect2
- PER1 | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 87/830 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs777594957; called by muse, varscan2
- PER1 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 64/472 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as rs1224877414; called by muse, mutect2, varscan2
- PER1 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.994); catalogued as rs201386026; called by muse, mutect2, varscan2
- PEX5L | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as rs779102712; called by muse, mutect2
- PHF14 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101301778; called by muse, mutect2, varscan2
- PHF20 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 259/617 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs764611258; called by muse, mutect2, varscan2
- PIK3C2B | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as COSV65803728; called by muse, mutect2, varscan2
- PKD1L1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 138/811 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs773738470, COSV56959115; called by muse, mutect2, varscan2
- PKD2L2 | c.1695G>A p.M565I | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV50364141; called by muse, mutect2
- PKHD1 | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 209/699 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866218539; called by muse, mutect2, varscan2
- PKNOX1 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 116/1166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs373371183; called by muse, mutect2
- PLAGL2 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs772248986; called by muse, mutect2
- PLD1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 62/478 reads (13%) | catalogued as COSV100579031; called by muse, mutect2, varscan2
- PLTP | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 167/1302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779125405; called by muse, varscan2
- PM20D1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 62/499 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65648901; called by muse, mutect2, varscan2
- PMS2 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 95/750 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs773393960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMS2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 142/1075 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs63750739, COSV56219696; called by muse, mutect2, varscan2
- POLR1A | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 39/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171271970; called by muse, mutect2, varscan2
- POLR3F | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs6136386; called by muse, mutect2, varscan2
- POTEF | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV100665051; called by muse, mutect2
- POTEF | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs1240788649; called by muse, mutect2
- POTEH | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 86/1276 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs756439385, COSV58882116; called by muse, varscan2
- PPFIA1 | c.3416C>T p.S1139L | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379410982; called by muse, mutect2, varscan2
- PRSS36 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs951361732; called by muse, mutect2
- PTPRO | c.3206C>T p.S1069L (on ENST00000281171 / NM_030667.3; = p.S1041L on NM_002848.4) | Missense Mutation (SNP) | VAF 30/1054 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV55508573; called by muse, mutect2
- RABGAP1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 156/1036 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs1482227640, COSV58059924; called by muse, mutect2, varscan2
- RAET1G | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 40/1497 reads (3%) | catalogued as rs1452430600; called by muse, mutect2
- RAPGEF6 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 55/640 reads (9%) | catalogued as COSV57244234; called by muse, mutect2
- RBAK-RBAKDN | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV101208251, COSV67760348; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs146851826; called by muse, mutect2, varscan2
- RBM6 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs775742397; called by muse, mutect2, varscan2
- REPS1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99238606; called by muse, varscan2
- RERE | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as rs762895746, COSV61942633; called by muse, mutect2
- RIC8A | c.132+3G>A | Splice Region (SNP) | VAF 15/96 reads (16%) | catalogued as rs1564798318; called by muse, mutect2, varscan2
- RNF113B | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 37/691 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV57436457; called by muse, mutect2
- RNF144B | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs771302398, COSV52568811; called by muse, mutect2, varscan2
- RNF213 | c.10690C>T p.L3564F | Missense Mutation (SNP) | VAF 75/705 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013216114; called by muse, mutect2, varscan2
- ROR1 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.26); catalogued as COSV64287717; called by muse, mutect2, varscan2
- RP1 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1563329489, COSV55111589; called by muse, mutect2, varscan2
- RPS14 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV100365245; called by muse, mutect2, varscan2
- RSL1D1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 41/646 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs766814935; called by muse, mutect2
- RUNX1T1 | c.163A>G p.T55A (on ENST00000265814 / NM_001198628.1; = p.T28A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/451 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV56160876; called by muse, mutect2, varscan2
- RYR1 | c.7205G>A p.R2402Q | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.539); catalogued as rs1316906057, COSV100617192; called by muse, mutect2
- SEL1L3 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs951782769, COSV53538451; called by muse, mutect2
- SEMA3C | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs147463830; called by muse, mutect2, varscan2
- SEZ6L2 | c.1684G>A p.E562K (on ENST00000308713 / NM_001114099.3; = p.E492K on NM_012410.4) | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs763922404; called by muse, mutect2, varscan2
- SFMBT2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/221 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1239735552, COSV62806101; called by muse, mutect2
- SH3D19 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58794603; called by muse, mutect2
- SHC1 | c.1364C>T p.P455L (on ENST00000368445 / NM_183001.5; = p.P346L on NM_003029.5) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as rs1369799407; called by muse, mutect2
- SHISA6 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 34/639 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs1422810500; called by muse, mutect2
- SHROOM2 | c.2320C>T p.L774F | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs759517110; called by muse, mutect2, varscan2
- SHROOM3 | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1267172166; called by muse, mutect2
- SHROOM4 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1557255450, COSV56799157, COSV99173007; called by muse, mutect2, varscan2
- SIPA1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.223); catalogued as rs1233823467; called by muse, mutect2, varscan2
- SLC12A6 | c.1036C>G p.L346V (on ENST00000354181 / NM_001365088.1; = p.L295V on NM_005135.2) | Missense Mutation (SNP) | VAF 101/1076 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1374588070; called by muse, mutect2
- SLC12A6 | c.808C>T p.L270F (on ENST00000354181 / NM_001365088.1; = p.L219F on NM_005135.2) | Missense Mutation (SNP) | VAF 87/1306 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1195273961; called by muse, mutect2
- SLC28A2 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 24/613 reads (4%) | catalogued as COSV61663158; called by muse, mutect2
- SLC37A1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 33/510 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs941104805; called by muse, mutect2
- SLC6A12 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 73/462 reads (16%) | catalogued as COSV62886285; called by muse, mutect2, varscan2
- SLC6A3 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as rs1221412674, COSV54362358; called by muse, mutect2, varscan2
- SLC6A7 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145923003; called by muse, mutect2
- SLC7A9 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1434090471, CD068565; called by muse, mutect2
- SLIT2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571492; called by muse, mutect2
- SMG7 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 78/632 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV61630034; called by muse, mutect2, varscan2
- SMIM3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 80/714 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.81); catalogued as rs766638068; called by muse, mutect2, varscan2
- SMIM3 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 81/712 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.856); catalogued as rs1158001066; called by muse, mutect2, varscan2
- SPATA17 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV65119512; called by muse, mutect2
- SPATA31D1 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100782843; called by muse, mutect2, varscan2
- SRPK2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 44/442 reads (10%) | catalogued as COSV61961906; called by muse, mutect2, varscan2
- SRRD | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs761271953, COSV99314665; called by muse, mutect2, varscan2
- STAB2 | c.7123G>A p.D2375N | Missense Mutation (SNP) | VAF 83/676 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1399934658; called by muse, mutect2, varscan2
- SYCE1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV58217074; called by muse, mutect2
- SYNM | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 186/1273 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs781881876, COSV60371794; called by muse, mutect2, varscan2
- TACR1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 85/749 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs200902232, COSV59485745; called by muse, mutect2, varscan2
- TACR3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 43/776 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866456567, COSV59197957; called by muse, mutect2
- TAF7L | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as rs866095249; called by muse, mutect2, varscan2
- TARS3 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1446310296; called by muse, mutect2
- TAS1R1 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs975043357; called by muse, mutect2, varscan2
- TFAP2A | c.631G>A p.E211K (on ENST00000482890; = p.E203K on NM_001032280.3) | Missense Mutation (SNP) | VAF 292/1016 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV60230419; called by muse, mutect2, varscan2
- TFG | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52526603; called by muse, mutect2, varscan2
- TG | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 36/830 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV55075236, COSV99601422; called by muse, mutect2
- TGFBR1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 84/952 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV66625921; called by muse, mutect2
- TGFBR1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 83/939 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs757374917, CM112279, COSV66624788; called by muse, mutect2
- TGFBR2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223854, CM076558, COSV55443169, COSV55454572; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- THOP1 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57021592; called by muse, mutect2
- TLN2 | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 64/897 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779849306, COSV60890149; called by muse, mutect2
- TMC1 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 59/742 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV52774675; called by muse, mutect2
- TMC8 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 58/643 reads (9%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.945); catalogued as rs559358892; called by muse, mutect2
- TMEM102 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV53440247; called by muse, mutect2, varscan2
- TMEM121B | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.814); catalogued as COSV100083598; called by muse, mutect2, varscan2
- TMEM121B | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.142); catalogued as COSV58897194; called by muse, mutect2, varscan2
- TMEM255B | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 87/634 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1052698331; called by muse, mutect2, varscan2
- TMPRSS11E | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV59521575; called by muse, mutect2
- TOR1AIP2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs751702177, COSV62625455; called by muse, mutect2
- TOX2 | c.238C>T p.P80S (on ENST00000358131 / NM_001098798.2; = p.P29S on NM_032883.3) | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100364401; called by muse, mutect2, varscan2
- TOX2 | c.239C>T p.P80L (on ENST00000358131 / NM_001098798.2; = p.P29L on NM_032883.3) | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541712879, COSV57885448; called by muse, mutect2, varscan2
- TOX3 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54865761; called by muse, mutect2
- TRAF4 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV99262225; called by muse, mutect2
- TRBV27 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372917970; called by muse, mutect2, varscan2
- TRIM36 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV56693749; called by muse, mutect2
- TRIM69 | c.848G>A p.G283E (on ENST00000329464 / NM_182985.5; = p.G124E on NM_080745.5) | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs775305195; called by muse, mutect2, varscan2
- TRIM9 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 47/556 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV53617279; called by muse, mutect2
- TRIP4 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 55/814 reads (7%) | catalogued as rs745835965, COSV99974662; called by muse, mutect2
- TRMT61B | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV60257406; called by muse, mutect2
- TRPM3 | c.2792G>A p.G931E (on ENST00000357533 / NM_001366142.2; = p.G774E on NM_020952.6) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV62585878; called by muse, mutect2, varscan2
- TSBP1 | c.519G>T p.M173I (on ENST00000617061; = p.M183I on NM_006781.5) | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV66660855; called by muse, mutect2
- TSNAXIP1 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV54650277; called by muse, mutect2, varscan2
- TSPOAP1 | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1430799074; called by muse, mutect2, varscan2
- TTN | c.79159G>A p.E26387K (on ENST00000591111; = p.E18963K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | PolyPhen benign (0.181); catalogued as rs1430846213; called by muse, mutect2
- TTN | c.47390G>A p.G15797E (on ENST00000591111; = p.G8373E on NM_003319.4) | Missense Mutation (SNP) | VAF 71/920 reads (8%) | PolyPhen benign (0.006); catalogued as rs1356720044, COSV59883740, COSV59927186; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.47389G>A p.G15797R (on ENST00000591111; = p.G8373R on NM_003319.4) | Missense Mutation (SNP) | VAF 73/909 reads (8%) | PolyPhen benign (0.018); catalogued as COSV60312489; called by muse, mutect2
- TTN | c.35165G>A p.R11722K (on ENST00000591111; = p.R10795K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | PolyPhen benign (0); catalogued as COSV60150456; called by muse, mutect2, varscan2
- TTN | c.17455C>T p.R5819* (on ENST00000591111; = p.R4892* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 109/1192 reads (9%) | catalogued as COSV100607456; called by muse, mutect2
- TTN | c.3304G>A p.G1102R (on ENST00000591111; = p.G1056R on NM_003319.4) | Missense Mutation (SNP) | VAF 58/1184 reads (5%) | PolyPhen benign (0.021); catalogued as rs1016142990, COSV59979446; called by muse, mutect2
- UGGT1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 39/464 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.847); catalogued as rs376225871, COSV52133745; called by muse, mutect2
- UGGT1 | c.4487C>T p.P1496L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269875891; called by muse, mutect2
- UGT3A2 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs61729692; called by muse, mutect2, varscan2
- UNC5C | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV101497845; called by muse, mutect2
- UNC80 | c.8035C>T p.R2679W | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs757992558, COSV55885176; called by muse, mutect2, varscan2
- USH2A | c.10667G>A p.G3556E | Missense Mutation (SNP) | VAF 44/608 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs397517968, COSV100232381, COSV56353201; ClinVar: uncertain significance; called by muse, mutect2
- USP13 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 110/581 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867861663; called by muse, mutect2, varscan2
- UTRN | c.8125G>A p.E2709K | Missense Mutation (SNP) | VAF 169/1005 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV100838627; called by muse, mutect2, varscan2
- VCAM1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs1421660194; called by muse, mutect2
- WDR49 | c.167G>A p.G56D (on ENST00000308378 / NM_001366158.1; = p.G397D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344720186; called by muse, mutect2
- WDR7 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757551227; called by muse, mutect2
- XPO7 | c.3142C>G p.R1048G | Missense Mutation (SNP) | VAF 131/655 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53019968; called by muse, mutect2, varscan2
- YTHDF1 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 23/302 reads (8%) | catalogued as COSV64833955; called by muse, mutect2
- ZBP1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 66/969 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs769676375; called by muse, mutect2
- ZBTB4 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as rs142195496; called by muse, mutect2, varscan2
- ZBTB49 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 30/726 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1447979824; called by muse, mutect2
- ZFHX2 | c.5770G>A p.V1924M | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs1400494881; called by muse, mutect2
- ZFHX4 | c.5172G>A p.M1724I | Missense Mutation (SNP) | VAF 30/677 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51480099, COSV51501632; called by muse, mutect2
- ZFP90 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.387); catalogued as COSV68050682, COSV68050688; called by muse, mutect2, varscan2
- ZFPM2 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 18/540 reads (3%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65876885; called by muse, mutect2
- ZFR2 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs552791449, COSV53601866; called by muse, mutect2, varscan2
- ZMYND8 | c.1657C>T p.R553C (on ENST00000311275 / NM_001363741.2; = p.R573C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/525 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs377161786, COSV53698760; called by muse, mutect2, varscan2
- ZNF469 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 73/398 reads (18%) | catalogued as COSV71258665; called by muse, mutect2, varscan2
- ZNF479 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100482551, COSV100482558; called by muse, mutect2, varscan2
- ZNF584 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100183256, COSV100183395; called by muse, mutect2, varscan2
- ZSCAN10 | c.802C>T p.L268F (on ENST00000252463; = p.L323F on NM_032805.3) | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs746738469; called by muse, mutect2
- A1CF | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 37/411 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); called by muse, mutect2
- AACS | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 82/660 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- AAR2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 291/640 reads (45%) | PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ABCB1 | c.2764C>T p.Q922* | Nonsense Mutation (SNP) | VAF 116/913 reads (13%) | called by muse, mutect2, varscan2
- ABCB1 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB6 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2
- ABCB9 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC011448.1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACD | c.806G>A p.G269E (on ENST00000620338; = p.G180E on NM_022914.3) | Missense Mutation (SNP) | VAF 31/540 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.15); called by muse, mutect2
- ADAMTS17 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 77/598 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.3335G>A p.G1112E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ADAMTS9 | c.4988A>C p.Q1663P | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTSL3 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 37/556 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- ADGRE3 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.37); called by muse, mutect2
- ADGRL2 | c.2399G>A p.G800E (on ENST00000370717 / NM_001366005.1; = p.G787E on NM_012302.4) | Missense Mutation (SNP) | VAF 26/673 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRV1 | c.5924C>T p.P1975L | Missense Mutation (SNP) | VAF 84/623 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGRN | c.5042G>A p.G1681E | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AHCTF1 | c.6353G>A p.R2118K (on ENST00000366508; = p.R2092K on NM_015446.5) | Missense Mutation (SNP) | VAF 56/805 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- AKAP11 | c.5591G>T p.G1864V | Missense Mutation (SNP) | VAF 34/747 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- AKAP12 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- AKAP13 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP6 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALMS1 | c.12061G>A p.G4021S | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ANAPC10 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANGPT4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANK2 | c.10565T>C p.V3522A | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- ANKDD1A | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.237); called by muse, mutect2
- ANKDD1A | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.237); called by muse, mutect2
- ANKRD10 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD11 | c.3000G>A p.W1000* | Nonsense Mutation (SNP) | VAF 72/936 reads (8%) | called by muse, mutect2
- ANKRD11 | c.2999G>A p.W1000* | Nonsense Mutation (SNP) | VAF 73/934 reads (8%) | called by muse, mutect2
- ANKRD24 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2
- ANKRD36 | c.2886G>A p.K962= | Splice Region (SNP) | VAF 62/1240 reads (5%) | called by muse, mutect2
- ANKRD36C | c.1240A>C p.I414L | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); called by muse, mutect2
- ANTXR1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- AP1S1 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 48/432 reads (11%) | called by muse, mutect2, varscan2
- APCDD1L | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- APOB | c.10300C>T p.P3434S | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AQP9 | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 25/257 reads (10%) | called by muse, mutect2
- AREL1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 35/569 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- ARFRP1 | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARHGAP26 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 46/623 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARMC4 | c.2496-1G>A p.X832_splice | Splice Site (SNP) | VAF 32/356 reads (9%) | called by muse, mutect2
- ARSJ | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2
- ASB15 | c.1413G>A p.W471* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- ASH1L | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ASIC1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- ASPHD1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ASS1 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 68/1068 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- ATP1B1 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2
- ATP1B1 | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- ATP6V0A4 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 122/813 reads (15%) | called by muse, mutect2, varscan2
- AUP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/395 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- AUTS2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- B4GALT1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BACH2 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BBS4 | c.25-1G>A p.X9_splice | Splice Site (SNP) | VAF 55/561 reads (10%) | called by muse, mutect2, varscan2
- BCAS4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); called by muse, mutect2
- BDP1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BICC1 | c.227T>G p.F76C | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- BICRA | c.4214C>T p.P1405L | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- BMPR2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 27/602 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- BPIFB2 | c.615T>G p.Y205* | Nonsense Mutation (SNP) | VAF 133/517 reads (26%) | called by muse, mutect2, varscan2
- BRD4 | c.3950C>T p.P1317L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.634); called by muse, mutect2
- BTBD8 | c.4366C>T p.H1456Y (on ENST00000636805 / NM_001376131.1; = p.H943Y on NM_015237.4) | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- C11orf54 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- C12orf42 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 69/709 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2
- C16orf86 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- C16orf86 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- C16orf89 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, varscan2
- C16orf96 | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C16orf96 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C18orf63 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- C1GALT1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf189 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 49/484 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- C4orf17 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2
- C7orf31 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- C7orf31 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CACNA1G | c.6716C>T p.S2239F | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CACNA1H | c.277T>C p.C93R | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- CACNA1S | c.5113G>A p.G1705S | Missense Mutation (SNP) | VAF 109/1076 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 67/671 reads (10%) | called by muse, mutect2
- CAMK1G | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.077); called by muse, mutect2
- CAMSAP1 | c.3182A>G p.K1061R | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- CARD6 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CARMIL3 | c.389del p.D130Afs*77 | Frame Shift Del (DEL) | VAF 29/275 reads (11%) | called by mutect2, varscan2
- CARMIL3 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 57/424 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CATSPER4 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 70/620 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, varscan2
- CCDC170 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 141/773 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CCN5 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- CCN5 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- CCNQ | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDH11 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.329); called by muse, mutect2
- CDH23 | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2
- CDH23 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.71); called by muse, mutect2
- CDH23 | c.3014C>T p.S1005F | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CDH9 | c.1590A>T p.E530D | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.168); called by muse, mutect2
- CDHR2 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 80/837 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- CDHR3 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, varscan2
- CDV3 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CECR2 | c.871G>A p.G291R (on ENST00000342247 / NM_001290047.2; = p.G128R on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2
- CEMIP2 | c.2267G>A p.R756K | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CENPF | c.9107C>T p.S3036F | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CEP120 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 77/523 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CERCAM | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CERT1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2
- CFAP46 | c.3836C>T p.P1279L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.104); called by muse, varscan2
- CFAP92 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD3 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); called by muse, mutect2
- CHPF | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CHRNB3 | c.703T>A p.F235I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHUK | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 82/851 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2
- CIBAR1 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 30/761 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- CLEC4F | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- CLIP4 | c.2083A>G p.I695V | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- CMKLR1 | c.986C>T p.A329V (on ENST00000312143 / NM_001142344.2; = p.A327V on NM_004072.3) | Missense Mutation (SNP) | VAF 77/672 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CNKSR2 | c.1733G>A p.W578* | Nonsense Mutation (SNP) | VAF 40/278 reads (14%) | called by muse, mutect2, varscan2
- CNTN6 | c.2787G>A p.M929I | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CNTNAP3B | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 54/541 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- COL14A1 | c.4455G>A p.K1485= | Splice Region (SNP) | VAF 42/421 reads (10%) | called by muse, varscan2
- COL15A1 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 154/958 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL17A1 | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 106/1067 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.628); called by muse, mutect2
- COL17A1 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 70/790 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL22A1 | c.3547G>A p.G1183S | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL24A1 | c.3971G>A p.G1324E | Missense Mutation (SNP) | VAF 24/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL24A1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A3 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.229); called by muse, mutect2
- CPNE1 | c.-196-1G>A | Splice Site (SNP) | VAF 321/865 reads (37%) | called by muse, mutect2, varscan2
- CPNE8 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CROCC2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CROCC2 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- CRYGS | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 61/680 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CSMD2 | c.6119G>A p.G2040E | Missense Mutation (SNP) | VAF 72/1244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSRNP3 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- CST1 | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 64/569 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CTSB | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CUBN | c.6853G>A p.G2285R | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2D7 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DAAM2 | c.88A>G p.N30D | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCC | c.2398A>C p.N800H | Missense Mutation (SNP) | VAF 64/816 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCDC2C | c.729G>A p.V243= | Splice Region (SNP) | VAF 42/582 reads (7%) | called by muse, mutect2
- DCHS1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.951); called by muse, mutect2
- DCLRE1A | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- DDO | c.726G>A p.W242* (on ENST00000368924 / NM_001368172.1; = p.W183* on NM_004032.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/225 reads (13%) | called by muse, mutect2, varscan2
- DDR2 | c.2532A>C p.E844D | Missense Mutation (SNP) | VAF 112/1060 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- DDX24 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- DDX24 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); called by muse, mutect2
- DENND3 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGCR6L | c.513+1G>A p.X171_splice | Splice Site (SNP) | VAF 54/732 reads (7%) | called by muse, mutect2
- DHDH | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, varscan2
- DMXL1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.10246G>A p.A3416T | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAH14 | c.589G>A p.E197K (on ENST00000445597; = p.E20K on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); called by muse, mutect2
- DNAH14 | c.6440G>A p.G2147E (on ENST00000445597; = p.G2800E on NM_001367479.1) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- DNAH3 | c.1794A>C p.K598N | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAH9 | c.6620C>T p.S2207F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNHD1 | c.1580T>A p.M527K | Missense Mutation (SNP) | VAF 36/795 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2
- DNHD1 | c.9595C>T p.Q3199* | Nonsense Mutation (SNP) | VAF 46/704 reads (7%) | called by muse, mutect2
- DTNB | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 68/842 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- DTX4 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- DUS1L | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUXB | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- DVL3 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- EDC4 | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 54/616 reads (9%) | called by muse, mutect2
- EDNRA | c.119T>A p.F40Y | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.024); called by muse, mutect2
- EFR3B | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- ELAC2 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 195/1204 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EPB41L4A | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ERICH6 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ESRRB | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- EXD1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EYA4 | c.1409A>G p.N470S (on ENST00000531901 / NM_001301013.1; = p.N464S on NM_004100.5) | Missense Mutation (SNP) | VAF 135/693 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EZH2 | c.1226-1G>A p.X409_splice (on ENST00000460911 / NM_001203247.2; = p.X414_splice on NM_004456.5) | Splice Site (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- F3 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2
- FAAH2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- FAM118B | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM172A | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2
- FAT2 | c.8794G>A p.D2932N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO6 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- FECH | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 48/624 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FEM1A | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 52/535 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); called by muse, mutect2
- FGD3 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 51/483 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FHAD1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- FICD | c.1070A>T p.Y357F | Missense Mutation (SNP) | VAF 23/594 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- FIGN | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.516); called by muse, mutect2
- FLI1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 195/1320 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- FLNB | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 109/895 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- FNBP4 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- FOXK1 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 145/772 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FREM1 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 196/796 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FREM2 | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.7136C>T p.S2379F | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FRMPD4 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FSIP2 | c.4193A>G p.N1398S | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.7498G>A p.E2500K | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); called by muse, mutect2
- FUT5 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 25/474 reads (5%) | called by muse, mutect2
- GAB1 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); called by muse, mutect2
- GASK1A | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- GCNA | c.1611G>A p.K537= | Splice Region (SNP) | VAF 32/237 reads (14%) | called by muse, mutect2, varscan2
- GCNA | c.1611+1G>A p.X537_splice | Splice Site (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- GFPT2 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 82/508 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- GLE1 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 168/1026 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GNAS | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2
- GPC2 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPR160 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GPR162 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, mutect2
- GRIK4 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 54/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRPR | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GTF3C3 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- GTPBP6 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 84/610 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GTSE1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- H3-5 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- HAP1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- HDAC9 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 79/657 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- HECTD4 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); called by muse, mutect2
- HERC2 | c.8401C>T p.L2801F | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEXA | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.663); called by muse, mutect2
- HIF3A | c.892C>T p.Q298* (on ENST00000377670 / NM_152795.4; = p.Q229* on NM_022462.4) | Nonsense Mutation (SNP) | VAF 24/388 reads (6%) | called by muse, mutect2
- HMCN2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.783G>A p.G261= | Splice Region (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- HNRNPCL2 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 40/848 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2
- HOGA1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HOGA1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB6 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXD3 | c.725T>G p.F242C | Missense Mutation (SNP) | VAF 24/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HPS5 | c.1546G>A p.D516N (on ENST00000349215 / NM_181507.2; = p.D402N on NM_007216.4) | Missense Mutation (SNP) | VAF 26/634 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- HROB | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 58/580 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- HS3ST6 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2
- HSH2D | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ICE1 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2
- IFI44L | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- IFIT2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2
- IGHV4-34 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 50/702 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2
- IGHV4-61 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 38/1160 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- IL16 | c.2141G>A p.W714* (on ENST00000302987 / NM_172217.5; = p.W13* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- ILF2 | c.657-1G>A p.X219_splice | Splice Site (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- ING1 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.22); called by muse, mutect2
- IPO5 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- IRF5 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ISM1 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IVNS1ABP | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 42/677 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.243); called by muse, mutect2
- IVNS1ABP | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 42/668 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2
- JADE1 | c.114A>T p.R38S | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2
- JPT2 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 58/551 reads (11%) | called by muse, mutect2, varscan2
- JUNB | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.078); called by muse, mutect2
- KANK1 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KANK4 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- KATNB1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2
- KCNJ5 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 139/647 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMA1 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 97/971 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM5D | c.4403G>A p.R1468Q | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- KDM5D | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIAA0586 | c.1004C>T p.P335L (on ENST00000619416 / NM_001244190.2; = p.P350L on NM_014749.5) | Missense Mutation (SNP) | VAF 30/562 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIDINS220 | c.1319A>T p.Y440F | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIDINS220 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 67/461 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- KIF21A | c.3137C>G p.S1046* (on ENST00000361418 / NM_001378440.1; = p.S1033* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/701 reads (8%) | called by muse, mutect2
- KIF2B | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, varscan2
- KIF5C | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF6 | c.559T>A p.L187M | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIT | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 32/762 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2
- KLF6 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 49/826 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2D | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2, varscan2
- KNOP1 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 31/320 reads (10%) | called by muse, mutect2
- KRT39 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 121/1115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LAMA1 | c.6755G>A p.G2252D | Missense Mutation (SNP) | VAF 48/658 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMF1 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LNX2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LPA | c.2743A>G p.T915A | Missense Mutation (SNP) | VAF 278/1482 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- LRRC4B | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRK1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 63/686 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2
- LSM14A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 47/579 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2
- LTBR | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 83/497 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- LY9 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 57/554 reads (10%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MACF1 | c.15928G>T p.D5310Y (on ENST00000372915; = p.D3243Y on NM_012090.5) | Missense Mutation (SNP) | VAF 28/267 reads (10%) | called by muse, mutect2, varscan2
- MAEL | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, varscan2
- MAGEB4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAMDC2 | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAN1A2 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.3); called by muse, mutect2
- MAN1A2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- MAP2K3 | c.502G>A p.E168K (on ENST00000342679 / NM_145109.3; = p.E139K on NM_002756.4) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MAP7D2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MAP7D2 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 132/713 reads (19%) | called by muse, mutect2, varscan2
- MBD4 | c.243A>T p.E81D | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MBD5 | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.027); called by muse, mutect2
- MCHR2 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCIDAS | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MCIDAS | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCTP1 | c.2951C>T p.P984L | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- METTL17 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- MFN2 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 39/560 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- MICOS13 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MITF | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 66/497 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MKI67 | c.8113C>T p.P2705S | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.547); called by muse, mutect2
- MMP10 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP20 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 129/864 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MN1 | c.2642G>A p.G881E | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MOGS | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 70/800 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- MROH5 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRPL32 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 137/768 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MSH4 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- MT1X | c.28+6G>A | Splice Region (SNP) | VAF 42/518 reads (8%) | called by muse, mutect2
- MTA1 | c.1076+1G>A p.X359_splice | Splice Site (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.15910G>A p.G5304R | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MUC16 | c.6068G>A p.G2023E | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MUC4 | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 104/985 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- MUC5B | c.10409C>A p.A3470D | Missense Mutation (SNP) | VAF 104/944 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, varscan2
- MUL1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 29/462 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2
- MYH1 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 73/655 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYO16 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- NAPSA | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- NBAS | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 64/858 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2
- NEK4 | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 30/373 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- NEMP1 | c.1148C>T p.P383L (on ENST00000300128 / NM_001130963.2; = p.P310L on NM_015257.3) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEURL1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- NEURL1 | c.85+1G>A p.X29_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- NEUROG1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NF2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2
- NFASC | c.1588G>A p.D530N (on ENST00000339876 / NM_001378329.1; = p.D541N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NFKBIA | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- NHLRC2 | c.2147G>A p.C716Y | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- NID1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 64/705 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NKAPL | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NLRP1 | c.449-1G>A p.X150_splice | Splice Site (SNP) | VAF 13/279 reads (5%) | called by muse, mutect2
- NLRP8 | c.3073A>C p.T1025P | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.175); called by muse, mutect2
- NME5 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.528); called by muse, mutect2
- NOA1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NOTCH1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 142/881 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH2 | c.5503G>A p.A1835T | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NPAT | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 121/921 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NR2F1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 64/566 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NRXN3 | c.1572C>G p.S524R | Missense Mutation (SNP) | VAF 34/577 reads (6%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.449); called by muse, mutect2
- NSUN6 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- OACYLP | n.1365C>T | Splice Region (SNP) | VAF 65/442 reads (15%) | called by muse, mutect2, varscan2
- OGFR | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- OPN1MW | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 114/716 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OPTC | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 64/1252 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- OR2AJ1 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- OR2L5 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 50/385 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR2M5 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- OR2V1 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 52/656 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- OR4C46 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 96/664 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K5 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- OR6F1 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OSBPL7 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.16); called by muse, mutect2
- OTOGL | c.4343T>G p.F1448C (on ENST00000547103; = p.F1439C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.677); called by muse, varscan2
- OVCA2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 70/826 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2
- OXSR1 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- P2RX4 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PADI6 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PALLD | c.2718-1G>A p.X906_splice (on ENST00000505667 / NM_001166108.2; = p.X889_splice on NM_016081.4) | Splice Site (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- PALLD | c.2718G>A p.R906= (on ENST00000505667 / NM_001166108.2; = p.R889= on NM_016081.4) | Splice Region (SNP) | VAF 18/367 reads (5%) | called by muse, mutect2
886 further variants in this file (199 protein-altering or splice-affecting, 476 silent, 211 other) are not listed here.
